Somatic mutation profile of tumor specimen ALCH-AEJ9-TTP1-A (aliquot ALCH-AEJ9-TTP1-A-1-0-D-A596-36) from ALCHEMIST case ALCH-AEJ9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 59.7 years (21,815 days).
Specimen ALCH-AEJ9-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 843322b4-1e01-4810-8fc4-0558c26f2b85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEJ9-NB1-A (Blood Derived Normal), aliquot ALCH-AEJ9-NB1-A-1-0-D-A596-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a76c2ed2-3dde-43fa-ac80-2ffe4ee89f09

The open-access MAF lists 659 somatic variants for this specimen: 448 protein-altering or splice-affecting, 127 silent, 84 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 393, Silent 127, Intron 32, Nonsense Mutation 28, 5'UTR 16, RNA 13, Frame Shift Del 12, 3'UTR 12, Splice Site 7, 5'Flank 6, 3'Flank 5, Splice Region 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 48/325 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377767345, CM100518, COSV61684254, COSV61684836, COSV61691577; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TFAP2A | c.773C>T p.A258V (on ENST00000482890; = p.A250V on NM_001032280.3) | Missense Mutation (SNP) | VAF 47/384 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs151344531, CM110094, COSV60233722; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.715A>G p.N239D | Missense Mutation (SNP) | VAF 59/355 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs876660807, COSV52664075, COSV52685174, COSV52979974, COSV53345856; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA5 | c.1470G>C p.K490N | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV101201278; called by muse, mutect2
- ABCG5 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 79/649 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765266332, COSV53212860; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMDEC1 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs541880302, COSV99835925; called by muse, mutect2, varscan2
- ADAMTS19 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.065); catalogued as COSV50733674; called by muse, mutect2, varscan2
- ADGB | c.3447G>C p.Q1149H | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1466970895, COSV62223089; called by muse, mutect2, varscan2
- ADGRE5 | c.571G>T p.G191C | Missense Mutation (SNP) | VAF 25/244 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99663390; called by muse, mutect2, varscan2
- ALG12 | c.1394C>T p.T465I | Missense Mutation (SNP) | VAF 42/345 reads (12%) | PolyPhen benign (0.052); catalogued as rs756851493; called by muse, mutect2, varscan2
- ALG6 | c.526T>C p.W176R | Missense Mutation (SNP) | VAF 30/267 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV99058230; called by muse, mutect2, varscan2
- ANKRD44 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 81/667 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs774866907; called by muse, mutect2, varscan2
- APC | c.7411C>T p.P2471S | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.489); catalogued as rs1324082067; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOF | c.326T>C p.L109P | Missense Mutation (SNP) | VAF 105/401 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as rs771898914; called by muse, mutect2, varscan2
- ARAP2 | c.2701C>G p.Q901E | Missense Mutation (SNP) | VAF 36/287 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV58290905; called by muse, mutect2, varscan2
- ASCC3 | c.1116G>C p.L372F | Missense Mutation (SNP) | VAF 48/435 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as rs1229402652; called by muse, mutect2, varscan2
- ASNS | c.1052A>G p.Y351C | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51552736; called by muse, mutect2, varscan2
- ATG7 | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs374506077; called by muse, mutect2, varscan2
- AXIN2 | c.1553A>G p.Y518C | Missense Mutation (SNP) | VAF 56/470 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs368289818; ClinVar: uncertain significance; called by muse, varscan2
- BCL7C | c.54C>G p.I18M | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs145988915; called by muse, mutect2, varscan2
- BMPR1B | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 73/417 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs1367092167, COSV99216404; called by muse, mutect2, varscan2
- BRINP1 | c.2135C>A p.P712Q | Missense Mutation (SNP) | VAF 56/315 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV56312556; called by muse, mutect2, varscan2
- C5 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.613); catalogued as rs773479432; called by muse, mutect2
- C7orf26 | c.1061A>T p.Q354L | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV60419750; called by muse, mutect2, varscan2
- CDC25B | c.1510C>T p.R504* (on ENST00000245960 / NM_021873.3; = p.R490* on NM_004358.4) | Nonsense Mutation (SNP) | VAF 24/116 reads (21%) | catalogued as rs1016651486, COSV55658897; called by muse, mutect2, varscan2
- CDH5 | c.2098G>A p.G700R | Missense Mutation (SNP) | VAF 21/350 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.118); catalogued as rs766859442; called by muse, mutect2
- CDH8 | c.1271del p.P424Lfs*2 | Frame Shift Del (DEL) | VAF 78/614 reads (13%) | catalogued as COSV54902606; called by mutect2, pindel, varscan2
- CGN | c.2809G>C p.E937Q | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.944); catalogued as rs752890105; called by muse, mutect2
- CLASP2 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV100224047; called by muse, mutect2, varscan2
- CLEC17A | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV60429837; called by muse, mutect2, varscan2
- CLEC7A | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1273871447, COSV53721905; called by muse, mutect2, varscan2
- CLPB | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 47/288 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV53627293; called by muse, mutect2, varscan2
- CNTNAP2 | c.949G>T p.G317* | Nonsense Mutation (SNP) | VAF 107/461 reads (23%) | catalogued as COSV62197909, COSV62201663; called by muse, mutect2, varscan2
- COL13A1 | c.1597G>T p.G533W (on ENST00000398978 / NM_001130103.2; = p.G476W on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/238 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62574355; called by muse, mutect2, varscan2
- COL6A3 | c.3325G>T p.G1109W | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99799944; called by muse, mutect2, varscan2
- COQ7 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs781712269; called by muse, mutect2, varscan2
- CPXCR1 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV99342386; called by muse, varscan2
- CRACDL | c.2749G>C p.A917P | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774138870; called by muse, mutect2, varscan2
- CSF2RB | c.296C>A p.P99H | Missense Mutation (SNP) | VAF 34/290 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.094); catalogued as COSV99453577; called by muse, mutect2, varscan2
- CSMD1 | c.5276C>A p.S1759Y (on ENST00000520002; = p.S1758Y on NM_033225.6) | Missense Mutation (SNP) | VAF 49/346 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1373035547; called by muse, mutect2, varscan2
- CSMD1 | c.2198G>A p.G733E (on ENST00000520002; = p.G732E on NM_033225.6) | Missense Mutation (SNP) | VAF 48/398 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100148719, COSV59276812; called by muse, varscan2
- CUL1 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 34/256 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57386633, COSV57390357; called by muse, mutect2, varscan2
- CYP8B1 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as rs368892456; called by muse, mutect2
- DOCK10 | c.2824G>T p.D942Y | Missense Mutation (SNP) | VAF 32/354 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1444286929, COSV51408347; called by muse, mutect2
- DOP1B | c.260A>G p.Y87C | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1203653162; called by muse, varscan2
- EEFSEC | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.121); catalogued as rs760525163; called by muse, mutect2, varscan2
- EHHADH | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV51630230; called by muse, mutect2
- ELOA2 | c.2258G>T p.R753L | Missense Mutation (SNP) | VAF 60/349 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1017975763, COSV55308508; called by muse, mutect2, varscan2
- ENAH | c.1563G>C p.Q521H | Missense Mutation (SNP) | VAF 18/285 reads (6%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.635); catalogued as rs1283729401; called by muse, mutect2
- EP400 | c.2012C>T p.A671V | Missense Mutation (SNP) | VAF 84/233 reads (36%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as rs774618050, COSV57776531; called by muse, mutect2, varscan2
- ERBB4 | c.2870G>T p.W957L | Missense Mutation (SNP) | VAF 34/392 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61515331; called by muse, mutect2
- FBXO4 | c.722G>A p.R241K | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.366); catalogued as rs577189527, COSV55853053; called by muse, mutect2, varscan2
- FCRLB | c.116G>C p.R39P | Missense Mutation (SNP) | VAF 43/434 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.638); catalogued as COSV61060176; called by muse, mutect2, varscan2
- FIZ1 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 33/240 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.154); catalogued as rs1439127187; called by muse, mutect2, varscan2
- FMN2 | c.1337G>T p.R446L | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV100145081, COSV60415433, COSV99070470; called by muse, mutect2, varscan2
- FTMT | c.200G>T p.R67L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV58419681; called by muse, mutect2, varscan2
- GIT1 | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as rs761142321; called by muse, mutect2
- GMCL2 | c.920C>G p.S307C | Missense Mutation (SNP) | VAF 60/467 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as rs747312562; called by muse, mutect2, varscan2
- GRIK4 | c.2407G>T p.E803* | Nonsense Mutation (SNP) | VAF 37/232 reads (16%) | catalogued as COSV70805216, COSV70805419; called by muse, mutect2, varscan2
- HBG2 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 131/2121 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs63751148, CM0910355, COSV57964828; ClinVar: other; called by muse, mutect2
- HIVEP1 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs776437287; called by muse, mutect2, varscan2
- HRG | c.441C>G p.F147L | Missense Mutation (SNP) | VAF 89/823 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as COSV51644228; called by muse, mutect2, varscan2
- IGKV3-15 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 24/412 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1335942503; called by muse, mutect2
- IGSF22 | c.1757G>T p.R586L | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs193141075; called by muse, mutect2, varscan2
- IGSF9B | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as rs370647370; called by muse, varscan2
- IL17RA | c.1046-1G>T p.X349_splice | Splice Site (SNP) | VAF 74/578 reads (13%) | catalogued as COSV60054618; called by muse, mutect2, varscan2
- IL17RA | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 44/694 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as rs779004550; ClinVar: uncertain significance; called by muse, mutect2
- INPP5E | c.895G>A p.V299M | Missense Mutation (SNP) | VAF 34/296 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as rs763020300; called by muse, mutect2, varscan2
- IRF4 | c.319T>G p.F107V | Missense Mutation (SNP) | VAF 29/252 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66706077; called by muse, mutect2, varscan2
- ISL1 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 52/465 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as rs768220738, COSV57933123; called by muse, mutect2, varscan2
- JRK | c.1424G>T p.G475V | Missense Mutation (SNP) | VAF 51/218 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV101401095; called by muse, mutect2, varscan2
- KIF2B | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs776017105, COSV52129130; called by muse, varscan2
- KIR2DL4 | c.1173G>C p.L391F (on ENST00000396284; = p.L317F on NM_001080770.2) | Missense Mutation (SNP) | VAF 136/776 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.65); catalogued as rs1329760374, COSV58493155; called by muse, mutect2, varscan2
- KLHL32 | c.515C>A p.S172Y | Missense Mutation (SNP) | VAF 116/740 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV100987140; called by muse, mutect2, varscan2
- KMT2C | c.57del p.E20Rfs*85 | Frame Shift Del (DEL) | VAF 23/100 reads (23%) | catalogued as COSV100067709, COSV51402237; called by mutect2, pindel, varscan2
- KRTAP10-11 | c.271A>G p.T91A | Missense Mutation (SNP) | VAF 59/483 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1426740991; called by muse, mutect2, varscan2
- LEFTY2 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 46/325 reads (14%) | catalogued as rs121909125, CM990492, COSV64747356; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LINC00634 | c.150G>T p.R50S | Missense Mutation (SNP) | VAF 38/264 reads (14%) | PolyPhen probably damaging (0.918); catalogued as rs960820457; called by muse, mutect2, varscan2
- LMX1A | c.350del p.L117Rfs*21 | Frame Shift Del (DEL) | VAF 71/675 reads (11%) | catalogued as COSV54227299; called by mutect2, pindel, varscan2
- LRP1B | c.3685G>T p.E1229* | Nonsense Mutation (SNP) | VAF 62/539 reads (12%) | catalogued as COSV67284991; called by muse, mutect2, varscan2
- LY9 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 100/416 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.1); catalogued as COSV54435922; called by muse, mutect2, varscan2
- MCF2L2 | c.624G>C p.L208F | Missense Mutation (SNP) | VAF 48/446 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV100193265; called by muse, mutect2, varscan2
- MFAP3 | c.913C>G p.L305V | Missense Mutation (SNP) | VAF 44/275 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV59456974; called by muse, mutect2, varscan2
- MRPL10 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 33/289 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs773720938; called by muse, mutect2, varscan2
- MYH7 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 63/302 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs1038661561; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH7B | c.1099A>G p.M367V | Missense Mutation (SNP) | VAF 31/258 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs757452082; called by muse, mutect2, varscan2
- NAA80 | c.827G>T p.G276V (on ENST00000417393 / NM_001200018.2; = p.G298V on NM_012191.4) | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs377507869; called by muse, mutect2, varscan2
- NBEA | c.8129G>T p.G2710V | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV59761766; called by muse, mutect2, varscan2
- NELFCD | c.1498G>C p.E500Q (on ENST00000602795; = p.E482Q on NM_198976.4) | Missense Mutation (SNP) | VAF 39/256 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.575); catalogued as COSV53883135; called by muse, mutect2, varscan2
- NLGN1 | c.1516G>T p.G506* | Nonsense Mutation (SNP) | VAF 55/438 reads (13%) | catalogued as COSV64335242; called by muse, mutect2, varscan2
- NPY5R | c.208C>G p.R70G | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV100642741; called by muse, mutect2, varscan2
- NTRK2 | c.1745G>T p.R582L (on ENST00000323115 / NM_001369534.1; = p.R598L on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/523 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs147652140; called by muse, mutect2, varscan2
- OGDH | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as rs772784260, COSV56051633; called by muse, mutect2, varscan2
- OR10A6 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as rs1270929577, COSV59165279; called by muse, varscan2
- OR2A5 | c.136G>T p.G46W | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV68738532; called by muse, varscan2
- OR2T1 | c.503G>T p.C168F | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63541636; called by muse, mutect2, varscan2
- OR4C12 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 45/407 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.027); catalogued as COSV100078644; called by muse, mutect2, varscan2
- OR51L1 | c.370C>A p.R124S | Missense Mutation (SNP) | VAF 36/276 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs143037587, COSV100386388, COSV58626143; called by muse, mutect2, varscan2
- OR52R1 | c.595C>A p.R199S | Missense Mutation (SNP) | VAF 46/335 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV61887825; called by muse, mutect2, varscan2
- OR6B2 | c.496G>T p.V166F | Missense Mutation (SNP) | VAF 39/462 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as rs199866112, COSV53156136; called by muse, varscan2
- P2RX2 | c.597C>G p.I199M (on ENST00000343948 / NM_170683.4; = p.I127M on NM_012226.5) | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57684117; called by muse, mutect2, varscan2
- PAPPA2 | c.3036C>A p.H1012Q | Missense Mutation (SNP) | VAF 64/274 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as rs1387946476, COSV62792924, COSV62815274; called by muse, mutect2, varscan2
- PCDHGA1 | c.844C>A p.H282N | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV65300605; called by muse, mutect2
- PCDHGA8 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 45/252 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as rs761723933, COSV99550446; called by muse, mutect2, varscan2
- PDE6B | c.1669C>A p.H557N | Missense Mutation (SNP) | VAF 42/343 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as CM950916, COSV99727973; called by muse, mutect2, varscan2
- PMFBP1 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 85/556 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.442); catalogued as rs1255917124; called by muse, mutect2, varscan2
- PPIB | c.607G>T p.G203C | Missense Mutation (SNP) | VAF 105/684 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55521688; called by muse, mutect2, varscan2
- PRCC | c.988A>T p.S330C | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); catalogued as COSV99618831; called by muse, mutect2, varscan2
- PSMB1 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 33/321 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51531498; called by muse, mutect2, varscan2
- QSER1 | c.3572C>T p.P1191L (on ENST00000399302; = p.P1320L on NM_001076786.3) | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV101234957; called by muse, mutect2, varscan2
- RASA2 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs751026479; called by muse, mutect2
- RGPD3 | c.2462C>A p.A821D | Missense Mutation (SNP) | VAF 36/450 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV58736840; called by muse, varscan2
- RIF1 | c.5887G>A p.E1963K | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV54616433; called by muse, mutect2, varscan2
- RNASE3 | c.86C>G p.P29R | Missense Mutation (SNP) | VAF 80/441 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58959301; called by muse, mutect2, varscan2
- RNASEH2A | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 92/613 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762016525; called by muse, mutect2, varscan2
- ROS1 | c.329T>C p.I110T | Missense Mutation (SNP) | VAF 50/318 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751815622, COSV63861778; called by muse, mutect2, varscan2
- S1PR4 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV55740657; called by muse, mutect2
- SCN11A | c.5048T>A p.M1683K | Missense Mutation (SNP) | VAF 38/217 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs1342813152; called by muse, mutect2, varscan2
- SCN1A | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 55/423 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as CM113265; called by muse, mutect2, varscan2
- SELP | c.833C>G p.S278C | Missense Mutation (SNP) | VAF 37/291 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.823); catalogued as COSV55250711; called by muse, mutect2, varscan2
- SEMA6A | c.2417G>A p.R806Q | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.787); catalogued as rs761738870, COSV56709021; called by muse, mutect2, varscan2
- SGIP1 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 38/280 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52766629; called by muse, mutect2, varscan2
- SLC12A3 | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as rs751725614, CM166515; called by muse, mutect2
- SLC17A8 | c.482G>C p.G161A | Missense Mutation (SNP) | VAF 148/595 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV60126137; called by muse, mutect2, varscan2
- SLC22A1 | c.782G>A p.W261* | Nonsense Mutation (SNP) | VAF 27/184 reads (15%) | catalogued as COSV104412199; called by muse, mutect2, varscan2
- SLC46A2 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as rs777593463; called by muse, mutect2, varscan2
- SLCO1C1 | c.1662C>G p.F554L | Missense Mutation (SNP) | VAF 123/489 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV56868784, COSV56871963; called by muse, mutect2, varscan2
- SLITRK2 | c.928C>A p.R310S | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.955); catalogued as COSV59425430; called by muse, mutect2, varscan2
- SLITRK3 | c.1432G>T p.G478C | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53850994; called by muse, mutect2
- SNAP91 | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.868); catalogued as rs769834926; called by muse, mutect2, varscan2
- SNRK | c.1065C>G p.I355M | Missense Mutation (SNP) | VAF 71/517 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as COSV56071235; called by muse, mutect2, varscan2
- SPATA5L1 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1393876025; called by muse, mutect2, varscan2
- SPINK5 | c.2765A>G p.Y922C | Missense Mutation (SNP) | VAF 123/708 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.76); catalogued as rs1050662109; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.533G>T p.R178L | Missense Mutation (SNP) | VAF 13/94 reads (14%) | PolyPhen probably damaging (0.973); catalogued as COSV59563661; called by muse, mutect2, varscan2
- SULT1C2 | c.420C>G p.Y140* | Nonsense Mutation (SNP) | VAF 23/180 reads (13%) | catalogued as COSV52266487; called by muse, mutect2, varscan2
- SVEP1 | c.9640G>C p.E3214Q | Missense Mutation (SNP) | VAF 62/282 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as COSV104400609, COSV52838435; called by muse, mutect2, varscan2
- TAS2R3 | c.729C>G p.F243L | Missense Mutation (SNP) | VAF 53/245 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV56091676; called by muse, mutect2, varscan2
- TCF20 | c.4499T>C p.V1500A | Missense Mutation (SNP) | VAF 45/283 reads (16%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs1439799540; called by muse, mutect2, varscan2
- TCF20 | c.4069C>T p.Q1357* | Nonsense Mutation (SNP) | VAF 64/485 reads (13%) | catalogued as COSV59495127; called by muse, varscan2
- TEX14 | c.2293G>C p.E765Q (on ENST00000240361 / NM_001201457.2; = p.E759Q on NM_031272.5) | Missense Mutation (SNP) | VAF 43/345 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV53620203, COSV53623473; called by muse, mutect2, varscan2
- TGFBR2 | c.884C>G p.S295* | Nonsense Mutation (SNP) | VAF 98/703 reads (14%) | catalogued as COSV55448334; called by muse, mutect2, varscan2
- THSD7B | c.3404G>T p.W1135L (on ENST00000272643; = p.W1133L on NM_001316349.2) | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55695488; called by muse, mutect2, varscan2
- TRAK2 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 54/314 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748387928, COSV60271858; called by muse, mutect2, varscan2
- TRIM42 | c.712T>G p.C238G | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as rs1383539542; called by muse, mutect2, varscan2
- TTC39B | c.1913G>T p.S638I | Missense Mutation (SNP) | VAF 56/298 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.139); catalogued as rs141433250; called by muse, mutect2, varscan2
- UBQLNL | c.1302G>A p.M434I | Missense Mutation (SNP) | VAF 37/534 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1490951445, COSV66492957; called by muse, mutect2
- UFM1 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 72/539 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); catalogued as rs750631146; called by muse, mutect2, varscan2
- USP10 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 52/321 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as rs1051412700, COSV99551747; called by muse, mutect2, varscan2
- VWC2L | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 53/386 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV56978405; called by muse, mutect2, varscan2
- XIRP1 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 48/368 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.984); catalogued as rs1043131171; called by muse, mutect2, varscan2
- ZKSCAN2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as COSV100048555; called by muse, mutect2, varscan2
- ZNF23 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 36/325 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs551966489; called by muse, mutect2, varscan2
- ZNF385B | c.1328C>A p.S443Y | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV61181775; called by muse, mutect2
- ZNF398 | c.546G>T p.M182I (on ENST00000475153 / NM_170686.3; = p.M11I on NM_020781.4) | Missense Mutation (SNP) | VAF 106/493 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1453445105, COSV60065638; called by muse, mutect2, varscan2
- ZNF44 | c.510C>G p.I170M (on ENST00000356109 / NM_001164276.2; = p.I122M on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/392 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.122); catalogued as rs773422494; called by muse, mutect2, varscan2
- ZNF552 | c.264G>C p.K88N | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV101197532; called by muse, mutect2, varscan2
- ZNF571 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 59/253 reads (23%) | catalogued as rs1284959181, COSV60733472; called by muse, mutect2, varscan2
- ZNF669 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV58538120; called by muse, mutect2
- ZNF773 | c.337C>A p.Q113K | Missense Mutation (SNP) | VAF 36/291 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs370538992; called by muse, mutect2, varscan2
- ZNF781 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 60/196 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.412); catalogued as COSV62200189, COSV62200259; called by muse, mutect2, varscan2
- ZZEF1 | c.7834G>A p.E2612K | Missense Mutation (SNP) | VAF 38/273 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs781010261; called by muse, mutect2, varscan2
- ABCC9 | c.966del p.Q323Sfs*3 | Frame Shift Del (DEL) | VAF 107/469 reads (23%) | called by mutect2, pindel, varscan2
- ABCG5 | c.611C>A p.A204E | Missense Mutation (SNP) | VAF 80/647 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACACA | c.1197C>G p.I399M | Missense Mutation (SNP) | VAF 68/418 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ACSM5 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 29/273 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- ADAMTS19 | c.2527C>T p.Q843* | Nonsense Mutation (SNP) | VAF 38/193 reads (20%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- ADGB | c.4684C>A p.Q1562K | Missense Mutation (SNP) | VAF 46/272 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- ADGRD2 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 95/443 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- AGTR1 | c.769C>A p.Q257K | Missense Mutation (SNP) | VAF 56/560 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2
- AHSG | c.502C>A p.L168M | Missense Mutation (SNP) | VAF 55/474 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- AKAP3 | c.994G>T p.D332Y | Missense Mutation (SNP) | VAF 71/377 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AMER2 | c.1750T>A p.L584I | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- AMH | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANO3 | c.2102dup p.L701Ffs*24 | Frame Shift Ins (INS) | VAF 42/438 reads (10%) | called by mutect2, pindel
- ANO7 | c.853G>T p.G285C (on ENST00000274979; = p.G231C on NM_001370694.2) | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ANO8 | c.2909T>A p.L970Q | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AP3B2 | c.1366T>C p.S456P | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- APOB | c.734G>T p.C245F | Missense Mutation (SNP) | VAF 83/717 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARID4B | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ASCC3 | c.1115T>G p.L372W | Missense Mutation (SNP) | VAF 49/450 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ASCL3 | c.131C>G p.P44R | Missense Mutation (SNP) | VAF 35/317 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- ATP10D | c.2317G>T p.D773Y | Missense Mutation (SNP) | VAF 84/447 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ATP7B | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 104/639 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ATP8A1 | c.2563G>T p.V855F | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- BACH2 | c.946C>G p.P316A | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.19); called by muse, mutect2
- BANP | c.1516C>T p.Q506* (on ENST00000286122; = p.Q456* on NM_017869.4) | Nonsense Mutation (SNP) | VAF 24/217 reads (11%) | called by muse, mutect2, varscan2
- BCHE | c.188A>T p.Q63L | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- BICD2 | c.1727A>C p.E576A | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- BRWD3 | c.887A>G p.Q296R | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- BTBD3 | c.1474G>A p.G492S | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- C17orf75 | c.322G>C p.G108R | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C3orf80 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2
- CACNA1F | c.3853G>A p.E1285K | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CALD1 | c.37del p.Q13Kfs*50 | Frame Shift Del (DEL) | VAF 34/195 reads (17%) | called by mutect2, pindel, varscan2
- CBLN1 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 54/377 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CCDC126 | c.208G>T p.V70F | Missense Mutation (SNP) | VAF 78/293 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2
- CCDC154 | c.596G>T p.R199L | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); called by muse, mutect2
- CCDC39 | c.2708C>A p.S903* | Nonsense Mutation (SNP) | VAF 113/434 reads (26%) | called by muse, mutect2, varscan2
- CCL17 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CCT8L2 | c.976del p.L326* | Frame Shift Del (DEL) | VAF 44/401 reads (11%) | called by mutect2, pindel, varscan2
- CD72 | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 50/688 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.186); called by muse, mutect2
- CDC45 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 52/397 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CDH19 | c.2177C>G p.T726R | Missense Mutation (SNP) | VAF 39/295 reads (13%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CDH19 | c.860A>T p.E287V | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- CETN1 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 56/403 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- CHAT | c.1842C>T p.A614= | Splice Region (SNP) | VAF 196/721 reads (27%) | called by muse, mutect2, varscan2
- CHD2 | c.2622C>G p.I874M | Missense Mutation (SNP) | VAF 83/578 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHRNG | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 15/317 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0.02); called by muse, mutect2
- CLGN | c.1235G>A p.G412D | Missense Mutation (SNP) | VAF 38/235 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLINT1 | c.1430G>T p.W477L | Missense Mutation (SNP) | VAF 123/950 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CMIP | c.784G>T p.V262L (on ENST00000537098 / NM_198390.2; = p.V168L on NM_030629.3) | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2
- CNGA4 | c.661A>T p.S221C | Missense Mutation (SNP) | VAF 53/398 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- CNPY4 | c.253A>T p.R85W | Missense Mutation (SNP) | VAF 57/254 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL11A2 | c.2123C>T p.S708F (on ENST00000341947 / NM_080680.3; = p.S601F on NM_080679.2) | Missense Mutation (SNP) | VAF 36/281 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- COL6A3 | c.6882A>G p.G2294= | Splice Region (SNP) | VAF 54/594 reads (9%) | called by muse, mutect2
- CPXCR1 | c.173C>A p.S58Y | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- CRIM1 | c.3041G>C p.R1014T | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- CRYZL1 | c.428C>G p.S143C | Missense Mutation (SNP) | VAF 41/306 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CSF1R | c.2391dup p.G798Rfs*4 | Frame Shift Ins (INS) | VAF 33/335 reads (10%) | called by mutect2, pindel, varscan2
- CSMD1 | c.960A>T p.R320S | Missense Mutation (SNP) | VAF 28/433 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.769); called by muse, mutect2
- CSMD3 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 113/465 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CUL9 | c.4691G>C p.G1564A | Missense Mutation (SNP) | VAF 29/269 reads (11%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- CWF19L2 | c.2551G>T p.G851C | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CXorf65 | c.112+3G>C | Splice Region (SNP) | VAF 32/109 reads (29%) | called by muse, mutect2, varscan2
- CYP3A7 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 36/350 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.597); called by muse, varscan2
- DAAM2 | c.1031G>T p.R344M | Missense Mutation (SNP) | VAF 38/245 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- DAPK3 | c.637G>C p.G213R | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCDC1 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.735); called by muse, mutect2
- DCHS1 | c.7940C>G p.S2647* | Nonsense Mutation (SNP) | VAF 39/336 reads (12%) | called by muse, mutect2, varscan2
- DENND5B | c.2775C>G p.F925L | Missense Mutation (SNP) | VAF 63/346 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.159); called by muse, varscan2
- DENND5B | c.2707C>G p.L903V | Missense Mutation (SNP) | VAF 57/308 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); called by muse, varscan2
- DMAC1 | c.219G>A p.M73I | Missense Mutation (SNP) | VAF 94/312 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- DMRTB1 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- DNAAF1 | c.769G>T p.V257F | Missense Mutation (SNP) | VAF 90/611 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- DNAH11 | c.12122C>T p.S4041F | Missense Mutation (SNP) | VAF 106/335 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- DNAJC12 | c.467A>C p.E156A | Missense Mutation (SNP) | VAF 68/262 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- DNASE2 | c.168G>C p.E56D | Missense Mutation (SNP) | VAF 46/310 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- DNHD1 | c.10289T>C p.L3430P | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- DPP8 | c.1561G>A p.V521I (on ENST00000341861 / NM_001320875.2; = p.V505I on NM_017743.6) | Missense Mutation (SNP) | VAF 30/279 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EHBP1L1 | c.704-1G>T p.X235_splice | Splice Site (SNP) | VAF 6/59 reads (10%) | called by muse, varscan2
- EHBP1L1 | c.769A>G p.R257G | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, varscan2
- EIF2B3 | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 100/682 reads (15%) | called by muse, mutect2, varscan2
- ENG | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.289); called by muse, mutect2
- EPSTI1 | c.923G>T p.W308L (on ENST00000398762 / NM_001330543.2; = p.W297L on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/422 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- ERICH6 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 42/288 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); called by muse, varscan2
- EZHIP | c.595G>T p.G199C | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- FAM111B | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 45/302 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FAM234A | c.403A>T p.T135S | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.024); called by muse, varscan2
- FAM47C | c.832G>C p.G278R | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, varscan2
- FAM47C | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.063); called by muse, varscan2
- FAT2 | c.9265G>C p.D3089H | Missense Mutation (SNP) | VAF 36/349 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCAR | c.816G>T p.M272I | Missense Mutation (SNP) | VAF 115/446 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- FERMT1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 25/964 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FGF6 | c.442T>A p.Y148N | Missense Mutation (SNP) | VAF 61/279 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSCB | c.1235T>A p.V412E | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- FSHR | c.1063C>A p.P355T | Missense Mutation (SNP) | VAF 50/389 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSIP2 | c.17116G>C p.D5706H | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- FUT9 | c.794C>A p.S265Y | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2
- GFRAL | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 42/370 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GNB1L | c.444G>T p.K148N | Missense Mutation (SNP) | VAF 44/345 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- GOLGB1 | c.4491A>T p.K1497N | Missense Mutation (SNP) | VAF 34/361 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPR149 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 39/355 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- GRIK4 | c.2406G>T p.M802I | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.346); called by muse, varscan2
- GRM3 | c.1693C>A p.L565I | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HACE1 | c.2677G>T p.D893Y | Missense Mutation (SNP) | VAF 61/588 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- HDAC3 | c.1058A>G p.Q353R | Missense Mutation (SNP) | VAF 58/465 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- HMHB1 | c.82G>C p.D28H | Missense Mutation (SNP) | VAF 37/323 reads (11%) | PolyPhen possibly damaging (0.487); called by muse, mutect2
- HSPA1B | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 152/1018 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- HSPBP1 | c.74_75insTGGCGGCG p.G29Afs*42 | Frame Shift Ins (INS) | VAF 51/193 reads (26%) | called by muse*, mutect2, varscan2*
- IGKC | c.296C>A p.T99K | Missense Mutation (SNP) | VAF 75/592 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- IGKV1D-8 | c.100T>A p.S34T | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- IGKV3-15 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 24/414 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.411); called by muse, mutect2
- IPO5 | c.1259G>C p.C420S | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IREB2 | c.2343C>G p.F781L | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ITGAX | c.2238C>G p.F746L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITLN1 | c.323C>A p.A108E | Missense Mutation (SNP) | VAF 61/432 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- KCNA2 | c.198G>A p.M66I | Missense Mutation (SNP) | VAF 53/237 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- KCNC1 | c.986T>A p.V329E | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNH1 | c.202A>T p.S68C | Missense Mutation (SNP) | VAF 50/220 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KCNH8 | c.3149C>G p.S1050* | Nonsense Mutation (SNP) | VAF 37/250 reads (15%) | called by muse, mutect2, varscan2
- KCNJ14 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIAA1549L | c.1610T>C p.L537P (on ENST00000321505; = p.L834P on NM_012194.3) | Missense Mutation (SNP) | VAF 45/314 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL32 | c.1672T>A p.W558R | Missense Mutation (SNP) | VAF 21/301 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- KLK3 | c.102T>A p.H34Q | Missense Mutation (SNP) | VAF 68/322 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- KNTC1 | c.2173G>C p.D725H | Missense Mutation (SNP) | VAF 80/273 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMA4 | c.1369G>T p.A457S (on ENST00000230538 / NM_001105206.3; = p.A450S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/455 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- LAMB2 | c.3344A>T p.H1115L | Missense Mutation (SNP) | VAF 67/373 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- LILRB2 | c.749G>C p.G250A | Missense Mutation (SNP) | VAF 44/270 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.761); called by muse, varscan2
- LINGO1 | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 37/199 reads (19%) | called by muse, mutect2, varscan2
- LMBRD2 | c.1510C>G p.H504D | Missense Mutation (SNP) | VAF 38/285 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- LPXN | c.560C>A p.S187Y | Missense Mutation (SNP) | VAF 43/476 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2
- LRCH3 | c.1426G>T p.V476L | Missense Mutation (SNP) | VAF 41/366 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- LRIF1 | c.2040T>G p.I680M | Missense Mutation (SNP) | VAF 80/518 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- LRRN4 | c.1325A>G p.N442S | Missense Mutation (SNP) | VAF 43/321 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K15 | c.1862A>G p.K621R | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAP4K3 | c.2179A>G p.M727V | Missense Mutation (SNP) | VAF 56/351 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- MARVELD2 | c.949del p.R317Efs*14 | Frame Shift Del (DEL) | VAF 86/779 reads (11%) | called by mutect2, pindel, varscan2
- MKI67 | c.6211C>T p.Q2071* | Nonsense Mutation (SNP) | VAF 17/234 reads (7%) | called by muse, mutect2
- MOV10 | c.1220A>T p.Q407L | Missense Mutation (SNP) | VAF 56/324 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MS4A3 | c.227A>T p.Y76F | Missense Mutation (SNP) | VAF 65/504 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- MSH6 | c.420G>T p.R140S | Missense Mutation (SNP) | VAF 76/500 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MSN | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.686); called by muse, mutect2
- MTCL1 | c.1015del p.E339Rfs*16 | Frame Shift Del (DEL) | VAF 23/180 reads (13%) | called by mutect2, pindel, varscan2
- MTCL1 | c.4304G>T p.W1435L (on ENST00000306329 / NM_001378206.1; = p.W1116L on NM_015210.4) | Missense Mutation (SNP) | VAF 44/287 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- MTF2 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MTNR1B | c.656G>A p.C219Y | Missense Mutation (SNP) | VAF 47/275 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC16 | c.9748A>T p.T3250S | Missense Mutation (SNP) | VAF 38/286 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MYB | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO18B | c.7272C>G p.F2424L | Missense Mutation (SNP) | VAF 39/349 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO7B | c.2222G>T p.G741V | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYOM1 | c.4799del p.P1600Rfs*8 | Frame Shift Del (DEL) | VAF 16/125 reads (13%) | called by mutect2, pindel, varscan2
- NAA11 | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NAAA | c.985C>G p.P329A | Missense Mutation (SNP) | VAF 50/258 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- NCAPD3 | c.602A>G p.N201S | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NELL2 | c.73G>C p.D25H | Missense Mutation (SNP) | VAF 82/333 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLRP4 | c.2003G>T p.R668L | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOD2 | c.2630+1G>T p.X877_splice | Splice Site (SNP) | VAF 79/704 reads (11%) | called by muse, mutect2, varscan2
- NOG | c.115G>C p.D39H | Missense Mutation (SNP) | VAF 44/336 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- NOS1AP | c.530A>T p.Q177L | Missense Mutation (SNP) | VAF 99/963 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NTPCR | c.424G>T p.G142C | Missense Mutation (SNP) | VAF 97/779 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUGGC | c.1464G>A p.M488I | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NWD2 | c.1634C>A p.T545K | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- NYAP2 | c.364C>A p.H122N | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OAS3 | c.726G>C p.K242N | Missense Mutation (SNP) | VAF 87/351 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- OR10G4 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 12/440 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR10X1 | c.632C>G p.T211R | Missense Mutation (SNP) | VAF 102/499 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- OR2G2 | c.546C>A p.C182* | Nonsense Mutation (SNP) | VAF 73/214 reads (34%) | called by muse, mutect2, varscan2
- OR2M5 | c.383A>T p.H128L | Missense Mutation (SNP) | VAF 104/443 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- OR6B1 | c.599T>G p.F200C | Missense Mutation (SNP) | VAF 20/524 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR9I1 | c.638T>C p.V213A | Missense Mutation (SNP) | VAF 61/504 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- PAPPA | c.2204C>T p.S735L | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2
- PARM1 | c.785T>C p.I262T | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PAX3 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 120/811 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- PAXBP1 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- PCDH15 | c.1546G>T p.V516L | Missense Mutation (SNP) | VAF 165/638 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- PCDHA10 | c.1898C>T p.T633M | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- PCLO | c.9949C>T p.Q3317* | Nonsense Mutation (SNP) | VAF 64/546 reads (12%) | called by muse, mutect2, varscan2
- PCSK6 | c.1440G>C p.L480F | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDIK1L | c.285+1G>T p.X95_splice | Splice Site (SNP) | VAF 10/65 reads (15%) | called by muse, varscan2
- PHF12 | c.856C>G p.L286V | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PICK1 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 62/418 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PLCL2 | c.1111C>A p.Q371K (on ENST00000615277 / NM_001144382.2; = p.Q245K on NM_015184.5) | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POGK | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 73/281 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- POTEG | c.330G>T p.R110S | Missense Mutation (SNP) | VAF 73/2082 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2
- PPIE | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRKCB | c.698A>T p.E233V | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, varscan2
- PRLR | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 55/313 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSKH1 | c.371A>G p.Y124C | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PTPN22 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- RASA1 | c.2780C>A p.A927E | Missense Mutation (SNP) | VAF 64/600 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- RAX | c.488T>C p.V163A | Missense Mutation (SNP) | VAF 47/265 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBMXL3 | c.108G>C p.K36N | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RELN | c.6037C>A p.L2013I | Missense Mutation (SNP) | VAF 111/445 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- RESF1 | c.4857del p.L1621Yfs*3 | Frame Shift Del (DEL) | VAF 22/79 reads (28%) | called by mutect2, pindel, varscan2
- RIF1 | c.2956-1G>A p.X986_splice | Splice Site (SNP) | VAF 19/174 reads (11%) | called by muse, mutect2, varscan2
- RIPK4 | c.2002G>A p.A668T (on ENST00000352483; = p.A620T on NM_020639.3) | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- RPL10L | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 45/362 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RXFP1 | c.1641G>C p.L547F | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.173); called by muse, mutect2
- SCN3A | c.5224G>T p.G1742W | Missense Mutation (SNP) | VAF 94/622 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN7A | c.3226G>T p.G1076* | Nonsense Mutation (SNP) | VAF 70/499 reads (14%) | called by muse, mutect2, varscan2
- SEC24D | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 49/240 reads (20%) | called by muse, mutect2, varscan2
- SECTM1 | c.234C>A p.F78L | Missense Mutation (SNP) | VAF 92/604 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- SELP | c.692C>A p.T231N | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- SEMA5B | c.1862G>C p.C621S | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEPTIN4 | c.1168A>T p.T390S | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.048); called by muse, varscan2
- SERPINA11 | c.372C>A p.H124Q | Missense Mutation (SNP) | VAF 50/327 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SETBP1 | c.691del p.V231Sfs*112 | Frame Shift Del (DEL) | VAF 45/399 reads (11%) | called by mutect2, pindel, varscan2
- SETD1A | c.796C>G p.Q266E | Missense Mutation (SNP) | VAF 53/400 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- SETD5 | c.1109A>T p.H370L | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SI | c.4016C>A p.P1339H | Missense Mutation (SNP) | VAF 87/494 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIPA1L3 | c.5000C>G p.S1667* | Nonsense Mutation (SNP) | VAF 22/75 reads (29%) | called by muse, mutect2, varscan2
- SIT1 | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.269); called by muse, mutect2
- SLC11A1 | c.1031A>T p.D344V | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- SLC12A3 | c.1966C>A p.P656T | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SLC16A10 | c.107C>A p.S36* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | called by muse, varscan2
- SLC17A9 | c.898C>T p.L300F | Missense Mutation (SNP) | VAF 38/259 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- SLC2A10 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 132/898 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SLCO1C1 | c.2060G>T p.R687I | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.045); called by muse, varscan2
- SLIT3 | c.1999T>A p.C667S | Missense Mutation (SNP) | VAF 40/285 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK3 | c.1433G>T p.G478V | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLU7 | c.312G>T p.R104S | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.33); called by muse, mutect2
- SMU1 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 36/359 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- SMYD1 | c.698G>T p.R233I | Missense Mutation (SNP) | VAF 36/312 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SMYD3 | c.1077-2A>T p.X359_splice (on ENST00000490107 / NM_001375962.1; = p.X300_splice on NM_022743.2 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 23/208 reads (11%) | called by muse, mutect2, varscan2
- SNAP25 | c.260T>G p.L87R | Missense Mutation (SNP) | VAF 44/245 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SND1 | c.213G>T p.K71N | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- SNX16 | c.61A>G p.T21A | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SOX14 | c.207G>A p.M69I | Missense Mutation (SNP) | VAF 40/327 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- SP4 | c.33G>T p.E11D | Missense Mutation (SNP) | VAF 79/302 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPAST | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SPATA31D1 | c.4114G>C p.E1372Q | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- SRD5A2 | c.502C>G p.R168G | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SRGAP1 | c.1437G>A p.R479= | Splice Region (SNP) | VAF 48/184 reads (26%) | called by muse, mutect2, varscan2
- SRPK3 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- STAB1 | c.1385C>A p.S462Y | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- STK16 | c.161A>T p.H54L | Missense Mutation (SNP) | VAF 85/575 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- STON2 | c.2919C>G p.I973M (on ENST00000649389 / NM_001366849.2; = p.I916M on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/89 reads (20%) | PolyPhen benign (0.286); called by muse, mutect2, varscan2
- STXBP1 | c.1599T>G p.S533R | Missense Mutation (SNP) | VAF 69/433 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); called by muse, varscan2
- STYXL2 | c.2407A>T p.T803S | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SULF1 | c.1759C>G p.L587V | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SVEP1 | c.3124G>A p.E1042K | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SYCE1L | c.655-5G>T | Splice Region (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2
- SYNE1 | c.16220T>A p.L5407Q (on ENST00000367255 / NM_182961.4; = p.L5336Q on NM_033071.3) | Missense Mutation (SNP) | VAF 56/374 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SYNE1 | c.1916C>T p.S639L (on ENST00000367255 / NM_182961.4; = p.S646L on NM_033071.3) | Missense Mutation (SNP) | VAF 74/643 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SYT14 | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 74/665 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TBC1D15 | c.1223G>A p.R408K | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- TECTA | c.1955G>T p.C652F | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEKT3 | c.943C>G p.R315G | Missense Mutation (SNP) | VAF 62/439 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- TEP1 | c.4268G>C p.R1423P | Missense Mutation (SNP) | VAF 44/251 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- TGFBI | c.1349A>T p.Y450F | Missense Mutation (SNP) | VAF 62/505 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- THBS2 | c.653A>G p.E218G | Missense Mutation (SNP) | VAF 44/377 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, varscan2
- TLL2 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 86/436 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM132C | c.715G>A p.G239R | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRAPPC2B | c.294C>A p.F98L | Missense Mutation (SNP) | VAF 66/631 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- TRBC2 | c.406-1G>C p.X136_splice | Splice Site (SNP) | VAF 82/281 reads (29%) | called by muse, mutect2, varscan2
- TRBV7-1 | c.298C>G p.R100G | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TRIM17 | c.544A>G p.R182G | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- TTC25 | c.1464G>T p.K488N | Missense Mutation (SNP) | VAF 38/323 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TTLL5 | c.290A>G p.N97S | Missense Mutation (SNP) | VAF 67/317 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, varscan2
- TTLL7 | c.2513C>T p.S838L | Missense Mutation (SNP) | VAF 41/348 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.26315A>T p.Y8772F (on ENST00000591111; = p.Y7845F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/260 reads (12%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UGT2A3 | c.414del p.Q139Rfs*7 | Frame Shift Del (DEL) | VAF 36/298 reads (12%) | called by mutect2, pindel, varscan2
- UMOD | c.1249C>A p.L417I | Missense Mutation (SNP) | VAF 50/481 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- USH2A | c.4889C>G p.S1630C | Missense Mutation (SNP) | VAF 62/576 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VKORC1 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 47/291 reads (16%) | called by muse, mutect2, varscan2
- VN1R2 | c.730G>T p.G244* | Nonsense Mutation (SNP) | VAF 127/697 reads (18%) | called by muse, mutect2, varscan2
- VWA3B | c.1049C>A p.T350K | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- WDFY4 | c.6077A>T p.Q2026L | Missense Mutation (SNP) | VAF 79/396 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- WDR90 | c.4117G>T p.E1373* | Nonsense Mutation (SNP) | VAF 30/196 reads (15%) | called by muse, mutect2, varscan2
- WIPF2 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- XIRP2 | c.6937G>C p.E2313Q (on ENST00000628543; = p.E2488Q on NM_152381.6) | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- XPOT | c.916T>A p.W306R | Missense Mutation (SNP) | VAF 95/373 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- ZBTB32 | c.98T>A p.I33N | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZC3H11A | c.2368G>T p.D790Y | Missense Mutation (SNP) | VAF 86/872 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- ZNF24 | c.203A>T p.E68V | Missense Mutation (SNP) | VAF 50/455 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF311 | c.110A>G p.Y37C | Missense Mutation (SNP) | VAF 36/251 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF396 | c.709A>T p.R237W | Missense Mutation (SNP) | VAF 154/628 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- ZNF521 | c.2750C>T p.A917V | Missense Mutation (SNP) | VAF 62/647 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- ZNF560 | c.1829C>A p.T610K | Missense Mutation (SNP) | VAF 42/331 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- ZNF614 | c.1592G>C p.R531T | Missense Mutation (SNP) | VAF 34/387 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF614 | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2
- ZNF618 | c.1172C>T p.P391L (on ENST00000374126 / NM_001318042.2; = p.P298L on NM_133374.2) | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); called by muse, varscan2
- ZNF626 | c.41C>G p.S14C | Missense Mutation (SNP) | VAF 52/427 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.798); called by muse, varscan2
- ZNF658 | c.2374C>T p.H792Y | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); called by mutect2, varscan2
- ZNF730 | c.927G>T p.E309D | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by mutect2, varscan2
- ZNF862 | c.2089G>C p.D697H | Missense Mutation (SNP) | VAF 66/197 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- ZSWIM6 | c.3227G>A p.C1076Y | Missense Mutation (SNP) | VAF 54/427 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC9 | c.2628G>A p.L876= | Silent (SNP) | VAF 184/723 reads (25%) | called by muse, mutect2, varscan2
- ABL2 | c.123C>T p.T41= | Silent (SNP) | VAF 24/194 reads (12%) | catalogued as rs755197010; called by muse, mutect2, varscan2
- ACAN | c.6192C>A p.P2064= | Silent (SNP) | VAF 47/315 reads (15%) | catalogued as COSV100717450, COSV61360078; called by muse, mutect2, varscan2
- ADAMTS18 | c.396T>A p.A132= | Silent (SNP) | VAF 56/464 reads (12%) | called by muse, mutect2, varscan2
- ADAMTSL2 | c.1932C>T p.F644= | Silent (SNP) | VAF 28/387 reads (7%) | catalogued as COSV63206754; called by muse, mutect2
- ADGRL4 | c.15G>C p.P5= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV66064525; called by muse, mutect2, varscan2
- AKAP4 | c.1323T>A p.T441= | Silent (SNP) | VAF 37/153 reads (24%) | catalogued as rs183292377; called by muse, mutect2, varscan2
- ANK1 | c.720C>T p.I240= | Silent (SNP) | VAF 54/392 reads (14%) | called by muse, mutect2, varscan2
- ARMC5 | c.303T>C p.S101= | Silent (SNP) | VAF 22/151 reads (15%) | called by muse, varscan2
- ARMC5 | c.420T>C p.C140= | Silent (SNP) | VAF 65/420 reads (15%) | catalogued as rs771406733; called by muse, varscan2
- ASPHD1 | c.681G>A p.V227= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs142768915; called by mutect2, varscan2
- ATP2B2 | c.810G>A p.R270= | Silent (SNP) | VAF 87/493 reads (18%) | catalogued as rs868297096, COSV59506554; called by muse, mutect2, varscan2
- BCL2A1 | c.432T>C p.F144= | Silent (SNP) | VAF 28/220 reads (13%) | called by muse, mutect2, varscan2
- BEST3 | c.1062C>T p.Y354= | Silent (SNP) | VAF 53/381 reads (14%) | called by muse, mutect2, varscan2
- BMP4 | c.351G>C p.V117= | Silent (SNP) | VAF 18/120 reads (15%) | called by muse, mutect2, varscan2
- C20orf144 | c.112C>A p.R38= | Silent (SNP) | VAF 33/150 reads (22%) | catalogued as COSV55775540, COSV99042752; called by muse, mutect2, varscan2
- C22orf23 | c.129G>A p.T43= | Silent (SNP) | VAF 24/274 reads (9%) | catalogued as rs12170918; called by muse, mutect2
- C3orf70 | c.258C>T p.A86= | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as rs1486984709; called by muse, mutect2
- CACNA1C | c.2578C>A p.R860= | Silent (SNP) | VAF 81/382 reads (21%) | catalogued as CM152259, COSV59734335; called by muse, mutect2, varscan2
- CD209 | c.60G>A p.L20= | Silent (SNP) | VAF 35/282 reads (12%) | called by muse, mutect2, varscan2
- CD40LG | c.244C>T p.L82= | Silent (SNP) | VAF 53/190 reads (28%) | called by muse, mutect2, varscan2
- CD84 | c.1008T>A p.P336= (on ENST00000311224 / NM_001184879.2; = p.P319= on NM_003874.4) | Silent (SNP) | VAF 109/546 reads (20%) | called by muse, mutect2, varscan2
- CHRND | c.300C>A p.V100= | Silent (SNP) | VAF 21/459 reads (5%) | catalogued as COSV51330845; called by muse, mutect2
- CMIP | c.783G>A p.E261= (on ENST00000537098 / NM_198390.2; = p.E167= on NM_030629.3) | Silent (SNP) | VAF 20/254 reads (8%) | catalogued as rs1217902656; called by muse, mutect2
- CNGA4 | c.423G>C p.L141= | Silent (SNP) | VAF 29/215 reads (13%) | catalogued as COSV66005203; called by muse, mutect2, varscan2
- CNKSR1 | c.1632G>A p.G544= (on ENST00000374253 / NM_001297647.2; = p.G537= on NM_006314.3) | Silent (SNP) | VAF 67/328 reads (20%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.831G>T p.V277= | Silent (SNP) | VAF 30/269 reads (11%) | called by muse, mutect2, varscan2
- COL12A1 | c.8124T>C p.I2708= | Silent (SNP) | VAF 35/436 reads (8%) | called by muse, mutect2
- COL19A1 | c.2802A>G p.P934= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as COSV100507924; called by muse, mutect2, varscan2
- COL3A1 | c.459C>T p.P153= | Silent (SNP) | VAF 50/549 reads (9%) | called by muse, mutect2
- COPG1 | c.291C>T p.C97= | Silent (SNP) | VAF 28/245 reads (11%) | called by muse, mutect2, varscan2
- CX3CL1 | c.414G>A p.L138= | Silent (SNP) | VAF 22/85 reads (26%) | called by muse, mutect2, varscan2
- DBNDD1 | c.270G>A p.E90= (on ENST00000002501 / NM_001042610.3; = p.E110= on NM_024043.3) | Silent (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
- DDX4 | c.1140G>A p.Q380= | Silent (SNP) | VAF 43/262 reads (16%) | catalogued as COSV61757049; called by muse, mutect2, varscan2
- DGKI | c.1143G>A p.V381= | Silent (SNP) | VAF 64/265 reads (24%) | called by muse, mutect2, varscan2
- DMD | c.7314T>A p.P2438= | Silent (SNP) | VAF 46/163 reads (28%) | called by muse, mutect2, varscan2
- DNAAF4 | c.990G>T p.R330= | Silent (SNP) | VAF 20/258 reads (8%) | called by muse, mutect2
- DNAH11 | c.2100C>T p.F700= | Silent (SNP) | VAF 67/239 reads (28%) | catalogued as rs756374306, COSV60947947; called by muse, mutect2, varscan2
- DNAH12 | c.7908T>A p.R2636= (on ENST00000351747; = p.R3504= on NM_001366028.2) | Silent (SNP) | VAF 28/138 reads (20%) | called by muse, varscan2
- DNAH5 | c.12969C>T p.T4323= | Silent (SNP) | VAF 106/744 reads (14%) | called by muse, mutect2, varscan2
- DPYSL3 | c.573G>C p.L191= | Silent (SNP) | VAF 51/400 reads (13%) | catalogued as COSV58325970; called by muse, mutect2, varscan2
- DUSP19 | c.48C>G p.L16= | Silent (SNP) | VAF 59/495 reads (12%) | called by muse, mutect2, varscan2
- DYNC2I2 | c.879G>A p.G293= | Silent (SNP) | VAF 18/110 reads (16%) | called by muse, mutect2, varscan2
- EAF2 | c.327A>T p.V109= | Silent (SNP) | VAF 39/345 reads (11%) | called by muse, mutect2, varscan2
- EDIL3 | c.888C>A p.L296= | Silent (SNP) | VAF 27/308 reads (9%) | catalogued as COSV56895371; called by muse, mutect2
- EPG5 | c.3609G>A p.R1203= | Silent (SNP) | VAF 45/365 reads (12%) | called by muse, mutect2, varscan2
- EVPL | c.1410A>T p.P470= | Silent (SNP) | VAF 37/202 reads (18%) | called by muse, mutect2, varscan2
- FAT3 | c.2217G>T p.L739= | Silent (SNP) | VAF 29/207 reads (14%) | catalogued as rs752381873; called by muse, mutect2, varscan2
- FAT4 | c.10611T>C p.P3537= | Silent (SNP) | VAF 58/388 reads (15%) | called by muse, mutect2, varscan2
- FBLN2 | c.1065C>A p.G355= | Silent (SNP) | VAF 31/174 reads (18%) | called by muse, mutect2, varscan2
- FBXO30 | c.1008A>G p.Q336= | Silent (SNP) | VAF 30/239 reads (13%) | catalogued as rs769311176; called by muse, mutect2, varscan2
- FLNB | c.6297C>T p.I2099= | Silent (SNP) | VAF 62/354 reads (18%) | called by muse, mutect2, varscan2
- FOXP4 | c.1836G>C p.V612= (on ENST00000307972 / NM_001012426.1; = p.V599= on NM_138457.3) | Silent (SNP) | VAF 21/122 reads (17%) | called by muse, mutect2, varscan2
- FST | c.360G>T p.P120= | Silent (SNP) | VAF 88/661 reads (13%) | called by muse, mutect2, varscan2
- GRID1 | c.384C>T p.C128= | Silent (SNP) | VAF 80/321 reads (25%) | called by muse, mutect2, varscan2
- HID1 | c.1719C>A p.T573= | Silent (SNP) | VAF 18/108 reads (17%) | called by muse, varscan2
- HLA-DOA | c.40C>T p.L14= | Silent (SNP) | VAF 19/158 reads (12%) | catalogued as rs973942479, COSV57714888; called by muse, mutect2, varscan2
- HMG20A | c.888T>C p.F296= | Silent (SNP) | VAF 42/217 reads (19%) | called by muse, mutect2, varscan2
- HOXB9 | c.642T>G p.R214= | Silent (SNP) | VAF 65/483 reads (13%) | catalogued as COSV60816529; called by muse, mutect2, varscan2
- HR | c.3018C>T p.L1006= | Silent (SNP) | VAF 80/509 reads (16%) | called by muse, mutect2, varscan2
- HTR4 | c.726G>A p.S242= | Silent (SNP) | VAF 29/219 reads (13%) | catalogued as rs199937786, COSV58802063; called by muse, mutect2, varscan2
- ID1 | c.294C>A p.V98= | Silent (SNP) | VAF 12/369 reads (3%) | called by muse, mutect2
- IFT80 | c.1815G>C p.V605= | Silent (SNP) | VAF 24/313 reads (8%) | catalogued as COSV100424410; called by muse, mutect2
- IGHV1-3 | c.306G>C p.L102= | Silent (SNP) | VAF 60/486 reads (12%) | catalogued as rs550477305; called by muse, mutect2, varscan2
- IGKV3D-11 | c.15G>T p.A5= | Silent (SNP) | VAF 32/367 reads (9%) | catalogued as rs369900920; called by muse, mutect2, varscan2
- IRF8 | c.852G>T p.R284= | Silent (SNP) | VAF 49/365 reads (13%) | called by muse, mutect2, varscan2
- KCNJ2 | c.867C>T p.N289= | Silent (SNP) | VAF 83/645 reads (13%) | catalogued as rs201909993; ClinVar: uncertain significance / benign / likely benign; called by muse, mutect2, varscan2
- KCNS1 | c.669C>T p.S223= | Silent (SNP) | VAF 29/217 reads (13%) | called by muse, mutect2, varscan2
- KCTD1 | c.723G>T p.R241= | Silent (SNP) | VAF 105/468 reads (22%) | called by muse, varscan2
- KCTD16 | c.897A>G p.K299= | Silent (SNP) | VAF 18/178 reads (10%) | called by muse, mutect2, varscan2
- LIPC | c.411C>T p.T137= | Silent (SNP) | VAF 32/185 reads (17%) | called by muse, mutect2, varscan2
- LRP2 | c.13617C>A p.I4539= | Silent (SNP) | VAF 95/790 reads (12%) | called by muse, mutect2, varscan2
- LYST | c.906G>A p.L302= | Silent (SNP) | VAF 53/218 reads (24%) | catalogued as rs767791732, COSV101090255; called by muse, mutect2, varscan2
- MALRD1 | c.3714C>T p.I1238= | Silent (SNP) | VAF 78/316 reads (25%) | catalogued as rs1267536013; called by muse, varscan2
- MIB1 | c.126C>T p.F42= | Silent (SNP) | VAF 33/244 reads (14%) | called by muse, mutect2, varscan2
- MPDU1 | c.402C>T p.L134= | Silent (SNP) | VAF 70/527 reads (13%) | catalogued as rs1216951728; called by muse, mutect2, varscan2
- MSI1 | c.159G>T p.R53= | Silent (SNP) | VAF 16/369 reads (4%) | called by muse, mutect2
- NEK10 | c.2419C>A p.R807= | Silent (SNP) | VAF 84/652 reads (13%) | called by muse, mutect2, varscan2
- NKD2 | c.936T>A p.P312= | Silent (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2, varscan2
- NPIPB2 | c.495A>G p.L165= (on ENST00000399147; = p.L25= on NM_001355514.1) | Silent (SNP) | VAF 76/649 reads (12%) | called by muse, mutect2, varscan2
- OPRPN | c.660T>C p.T220= | Silent (SNP) | VAF 31/132 reads (23%) | catalogued as rs762740998; called by muse, mutect2, varscan2
- OR10G7 | c.255C>T p.S85= | Silent (SNP) | VAF 36/406 reads (9%) | catalogued as COSV100389687, COSV57867441; called by muse, mutect2
- OR5B17 | c.382C>T p.L128= | Silent (SNP) | VAF 25/146 reads (17%) | called by muse, mutect2, varscan2
- PCDHB8 | c.306C>G p.P102= | Silent (SNP) | VAF 38/966 reads (4%) | called by muse, mutect2
- PCNX3 | c.2997G>A p.L999= | Silent (SNP) | VAF 22/178 reads (12%) | called by muse, mutect2, varscan2
- PCSK9 | c.1002C>T p.I334= | Silent (SNP) | VAF 54/440 reads (12%) | catalogued as rs1252162207; called by muse, mutect2, varscan2
- PDZD2 | c.1572G>C p.R524= | Silent (SNP) | VAF 14/440 reads (3%) | catalogued as COSV56857416; called by muse, mutect2
- PIGO | c.2997G>T p.R999= | Silent (SNP) | VAF 30/247 reads (12%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.9333T>A p.G3111= | Silent (SNP) | VAF 32/135 reads (24%) | called by muse, varscan2
- PLEC | c.3453G>A p.E1151= (on ENST00000322810 / NM_201380.4; = p.E1041= on NM_000445.5) | Silent (SNP) | VAF 54/138 reads (39%) | catalogued as rs1223782760; called by muse, mutect2, varscan2
- RAB3GAP2 | c.552A>G p.P184= | Silent (SNP) | VAF 78/717 reads (11%) | called by muse, mutect2, varscan2
- RBM22 | c.1086C>T p.N362= | Silent (SNP) | VAF 20/125 reads (16%) | catalogued as COSV52271394; called by muse, mutect2, varscan2
- RBMXL2 | c.127C>A p.R43= | Silent (SNP) | VAF 96/742 reads (13%) | called by muse, mutect2, varscan2
- RPP25L | c.33G>A p.E11= | Silent (SNP) | VAF 15/145 reads (10%) | called by muse, varscan2
- RSBN1 | c.2064A>T p.T688= | Silent (SNP) | VAF 42/315 reads (13%) | called by muse, mutect2, varscan2
- RYR2 | c.14586A>T p.I4862= | Silent (SNP) | VAF 13/145 reads (9%) | catalogued as COSV63685679; called by muse, mutect2
- SARDH | c.702C>T p.N234= | Silent (SNP) | VAF 17/178 reads (10%) | called by muse, mutect2
- SART3 | c.516C>T p.L172= | Silent (SNP) | VAF 142/486 reads (29%) | catalogued as COSV57210745; called by muse, mutect2, varscan2
- SIGLEC1 | c.1893C>A p.P631= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as rs753404501, COSV52460682; called by muse, mutect2, varscan2
- SIGLEC6 | c.55C>T p.L19= | Silent (SNP) | VAF 62/197 reads (31%) | called by muse, mutect2, varscan2
- SLC13A4 | c.60G>T p.P20= | Silent (SNP) | VAF 50/197 reads (25%) | called by muse, mutect2, varscan2
- SLC6A5 | c.1287G>A p.P429= | Silent (SNP) | VAF 66/490 reads (13%) | catalogued as rs536309591; called by muse, mutect2, varscan2
- SLCO1C1 | c.1947G>T p.L649= | Silent (SNP) | VAF 16/114 reads (14%) | called by muse, varscan2
- TCERG1L | c.798G>A p.P266= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs767355246, COSV64058406; called by muse, mutect2, varscan2
- TDRD7 | c.3135G>A p.E1045= | Silent (SNP) | VAF 123/680 reads (18%) | called by muse, mutect2, varscan2
- TENM1 | c.4290C>T p.A1430= | Silent (SNP) | VAF 81/261 reads (31%) | catalogued as rs762879040; called by muse, mutect2, varscan2
- THSD7B | c.1437C>A p.I479= | Silent (SNP) | VAF 29/248 reads (12%) | catalogued as rs751892896, COSV55682244, COSV55729033; called by muse, mutect2, varscan2
- TIMM29 | c.237C>T p.S79= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs1339245284; called by muse, mutect2, varscan2
- TLX3 | c.339C>G p.S113= | Silent (SNP) | VAF 25/179 reads (14%) | catalogued as COSV51542141; called by muse, mutect2, varscan2
- TMC6 | c.1548C>G p.L516= | Silent (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- TMEM72 | c.57C>T p.I19= | Silent (SNP) | VAF 38/214 reads (18%) | called by muse, mutect2, varscan2
- TNK1 | c.1125G>A p.G375= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as rs1469486859; called by muse, mutect2, varscan2
- TRIM28 | c.2328T>C p.T776= | Silent (SNP) | VAF 69/230 reads (30%) | called by muse, mutect2, varscan2
- TTLL12 | c.1272G>T p.A424= | Silent (SNP) | VAF 21/150 reads (14%) | called by muse, mutect2, varscan2
- TTN | c.42618C>A p.A14206= (on ENST00000591111; = p.A6782= on NM_003319.4) | Silent (SNP) | VAF 81/641 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.38550C>A p.I12850= (on ENST00000591111; = p.I5426= on NM_003319.4) | Silent (SNP) | VAF 35/284 reads (12%) | called by muse, mutect2, varscan2
- UBE2R2 | c.411C>T p.F137= | Silent (SNP) | VAF 45/414 reads (11%) | called by muse, mutect2, varscan2
- UNC50 | c.252C>T p.F84= | Silent (SNP) | VAF 32/162 reads (20%) | called by muse, mutect2, varscan2
- USH2A | c.12489C>T p.V4163= | Silent (SNP) | VAF 27/197 reads (14%) | called by muse, mutect2, varscan2
- WNK2 | c.5694G>T p.V1898= (on ENST00000297954 / NM_001282394.1; = p.V1861= on NM_006648.3) | Silent (SNP) | VAF 8/120 reads (7%) | catalogued as COSV99944427; called by muse, mutect2
- ZFHX4 | c.9774A>T p.I3258= | Silent (SNP) | VAF 57/214 reads (27%) | catalogued as rs1368221230; called by muse, mutect2, varscan2
- ZFP28 | c.822A>G p.P274= | Silent (SNP) | VAF 42/342 reads (12%) | called by muse, mutect2, varscan2
- ZNF487 | c.288A>G p.R96= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as rs1246430600; called by muse, mutect2, varscan2
- ZNF611 | c.1521G>A p.E507= | Silent (SNP) | VAF 95/273 reads (35%) | catalogued as rs780930363, COSV60539717; called by muse, mutect2, varscan2
- ZNF716 | c.66T>A p.A22= | Silent (SNP) | VAF 66/301 reads (22%) | catalogued as COSV70782160; called by muse, mutect2, varscan2
- ZNF761 | c.1884T>C p.H628= | Silent (SNP) | VAF 61/347 reads (18%) | called by muse, mutect2, varscan2
- ZXDC | c.1626C>A p.V542= | Silent (SNP) | VAF 32/272 reads (12%) | called by muse, mutect2, varscan2
- ABCC6P1 | n.1157C>T | RNA (SNP) | VAF 74/597 reads (12%) | called by muse, varscan2
- ABCC8 | c.1817+20G>C | Intron (SNP) | VAF 48/506 reads (9%) | called by muse, mutect2
- ABTB1 | c.-42C>T | 5'UTR (SNP) | VAF 28/306 reads (9%) | catalogued as rs200194975, COSV99229578; called by muse, mutect2
- AC092329.3 | c.-211-378C>G | Intron (SNP) | VAF 47/334 reads (14%) | called by muse, mutect2, varscan2
- AC103796.1 | n.148-24900A>T | Intron (SNP) | VAF 57/535 reads (11%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-10004G>A | Intron (SNP) | VAF 27/227 reads (12%) | called by muse, mutect2, varscan2
- AC245884.12 | n.17C>T | RNA (SNP) | VAF 65/585 reads (11%) | called by muse, mutect2, varscan2
- ACO1 | c.-1C>A | 5'UTR (SNP) | VAF 54/404 reads (13%) | catalogued as COSV59382443; called by muse, mutect2, varscan2
- ALX1 | c.-4G>T | 5'UTR (SNP) | VAF 45/137 reads (33%) | catalogued as rs752310288; called by muse, mutect2, varscan2
- AP000679.1 | n.393del | RNA (DEL) | VAF 20/142 reads (14%) | called by mutect2, pindel, varscan2
- APOOP5 | n.272G>T | RNA (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- APOOP5 | chr16:59751969 G>A | 3'Flank (SNP) | VAF 27/167 reads (16%) | called by muse, mutect2, varscan2
- ARMC5 | c.-11C>G | 5'UTR (SNP) | VAF 33/308 reads (11%) | called by muse, mutect2
- BEAN1 | chr16:66482947 C>A | 3'Flank (SNP) | VAF 38/197 reads (19%) | catalogued as rs769697767; called by muse, mutect2, varscan2
- BRD2 | c.-835C>G | 5'UTR (SNP) | VAF 13/91 reads (14%) | catalogued as rs777890525; called by muse, mutect2
- BTNL8 | c.-11A>C | 5'UTR (SNP) | VAF 41/325 reads (13%) | called by muse, mutect2, varscan2
- C2CD6 | c.1582-3480G>C | Intron (SNP) | VAF 42/224 reads (19%) | called by muse, mutect2, varscan2
- CABLES1 | c.845+19307G>A | Intron (SNP) | VAF 52/481 reads (11%) | called by muse, mutect2
- CD55 | c.*30C>T | 3'UTR (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- CHL1 | c.-175+749del | Intron (DEL) | VAF 26/137 reads (19%) | catalogued as rs1360813697; called by mutect2, pindel, varscan2
- CISD1 | c.-43G>C | 5'UTR (SNP) | VAF 67/304 reads (22%) | called by muse, mutect2, varscan2
- DMD | c.9808-21C>G | Intron (SNP) | VAF 25/114 reads (22%) | called by muse, mutect2, varscan2
- DNM1 | c.1336-1928G>A | Intron (SNP) | VAF 14/92 reads (15%) | catalogued as rs1371436011; called by muse, mutect2, varscan2
- EIPR1 | c.259+19062A>C | Intron (SNP) | VAF 38/265 reads (14%) | called by muse, mutect2, varscan2
- EPB41L2 | c.2043+1363C>T | Intron (SNP) | VAF 20/175 reads (11%) | called by muse, mutect2, varscan2
- FANCF | chr11:22625853 G>T | 5'Flank (SNP) | VAF 34/276 reads (12%) | called by muse, mutect2, varscan2
- FIS1 | c.*99G>T | 3'UTR (SNP) | VAF 48/127 reads (38%) | called by muse, mutect2, varscan2
- FKTN | c.*1513G>A | 3'UTR (SNP) | VAF 10/174 reads (6%) | called by muse, mutect2
- GCLC | c.1484-22C>T | Intron (SNP) | VAF 134/933 reads (14%) | called by muse, mutect2, varscan2
- GUSB | c.912+92A>T | Intron (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2
- HAO1 | c.*5G>C | 3'UTR (SNP) | VAF 44/368 reads (12%) | called by muse, mutect2, varscan2
- HLX | c.957+41G>T | Intron (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- HTR4 | c.-21C>G | 5'UTR (SNP) | VAF 26/240 reads (11%) | called by muse, mutect2, varscan2
- IGSF1 | c.-153C>A | 5'UTR (SNP) | VAF 18/66 reads (27%) | called by muse, mutect2, varscan2
- INTS4 | c.2228+753G>T | Intron (SNP) | VAF 17/150 reads (11%) | called by muse, varscan2
- ITGA4 | c.*1837del | 3'UTR (DEL) | VAF 30/262 reads (11%) | called by mutect2, pindel, varscan2
- KDM2A | c.*502G>T | 3'UTR (SNP) | VAF 31/213 reads (15%) | called by muse, mutect2, varscan2
- KNOP1P1 | n.290C>G | RNA (SNP) | VAF 34/79 reads (43%) | catalogued as rs528057305; called by muse, mutect2, varscan2
- LILRB5 | c.1630-99G>T | Intron (SNP) | VAF 51/234 reads (22%) | called by muse, mutect2, varscan2
- LINC02860 | n.1050C>T | RNA (SNP) | VAF 110/411 reads (27%) | called by muse, mutect2, varscan2
- MAPK14 | c.763-2306G>A | Intron (SNP) | VAF 52/439 reads (12%) | called by muse, mutect2, varscan2
- MARF1 | c.831+35C>T | Intron (SNP) | VAF 10/60 reads (17%) | called by muse, varscan2
- MARK1 | c.-5A>G | 5'UTR (SNP) | VAF 19/173 reads (11%) | called by muse, mutect2, varscan2
- MRM2 | chr7:2242212 C>T | 5'Flank (SNP) | VAF 8/67 reads (12%) | catalogued as rs1192828851; called by muse, mutect2, varscan2
- MUC19 | chr12:40544384 G>T | 3'Flank (SNP) | VAF 21/144 reads (15%) | called by muse, mutect2, varscan2
- MUC20P1 | n.970C>G | RNA (SNP) | VAF 30/872 reads (3%) | called by muse, mutect2
- NDUFAF7 | c.622+25G>C | Intron (SNP) | VAF 19/149 reads (13%) | called by muse, mutect2, varscan2
- NEUROG1 | c.-1G>A | 5'UTR (SNP) | VAF 4/28 reads (14%) | catalogued as rs1194896653; called by muse, mutect2
- OR5P1P | n.357G>C | RNA (SNP) | VAF 23/159 reads (14%) | catalogued as rs775113519; called by muse, mutect2, varscan2
- ORC6 | c.*252G>C | 3'UTR (SNP) | VAF 50/353 reads (14%) | called by muse, mutect2, varscan2
- PABPN1L | c.*98G>A | 3'UTR (SNP) | VAF 31/206 reads (15%) | catalogued as rs867530143; called by muse, mutect2, varscan2
- PCSK5 | c.3523+5290A>T | Intron (SNP) | VAF 27/272 reads (10%) | called by muse, mutect2
- PKD1P6 | n.4457G>T | RNA (SNP) | VAF 65/511 reads (13%) | called by muse, mutect2, varscan2
- PKNOX2 | c.817-77C>A | Intron (SNP) | VAF 30/241 reads (12%) | called by muse, mutect2, varscan2
- POLL | chr10:101588254 G>A | 5'Flank (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
- PPAN | c.*586G>T | 3'UTR (SNP) | VAF 41/274 reads (15%) | called by muse, mutect2, varscan2
- PPP2R5C | c.94+8954A>G | Intron (SNP) | VAF 49/340 reads (14%) | called by muse, mutect2
- PRB4 | c.*9T>C | 3'UTR (SNP) | VAF 35/111 reads (32%) | called by muse, mutect2, varscan2
- PROP1 | c.-50G>C | 5'UTR (SNP) | VAF 16/273 reads (6%) | called by muse, mutect2
- PRR16 | c.159+16552G>T | Intron (SNP) | VAF 21/177 reads (12%) | called by muse, mutect2, varscan2
- RALYL | c.*11C>G | 3'UTR (SNP) | VAF 13/94 reads (14%) | called by muse, mutect2, varscan2
- RARA | c.179-5525C>G | Intron (SNP) | VAF 16/244 reads (7%) | called by muse, mutect2
- RPS13 | c.-13G>A | 5'UTR (SNP) | VAF 30/218 reads (14%) | catalogued as rs1473628929, COSV57179954; called by muse, mutect2, varscan2
- RTN4RL2 | c.513+723T>C | Intron (SNP) | VAF 43/436 reads (10%) | catalogued as rs1315259765; called by muse, mutect2
- RUBCN | c.-11C>T | 5'UTR (SNP) | VAF 28/191 reads (15%) | catalogued as rs1004700218; called by muse, mutect2, varscan2
- SGIP1 | c.1315+1787A>C | Intron (SNP) | VAF 40/427 reads (9%) | called by muse, mutect2
- SGSH | chr17:80220340 G>A | 5'Flank (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2
- SINHCAF | c.-21+1124G>C | Intron (SNP) | VAF 31/90 reads (34%) | called by muse, mutect2, varscan2
- SNORD116-15 | n.34G>A | RNA (SNP) | VAF 38/360 reads (11%) | called by muse, mutect2, varscan2
- SORBS1 | chr10:95441173 G>A | 5'Flank (SNP) | VAF 91/244 reads (37%) | called by muse, mutect2, varscan2
- SPTLC3 | c.303+22G>T | Intron (SNP) | VAF 19/156 reads (12%) | called by muse, mutect2, varscan2
- SRRM2 | c.-183C>T | 5'UTR (SNP) | VAF 9/47 reads (19%) | catalogued as rs772090069; called by muse, mutect2, varscan2
- SYT14 | chr1:210163173 G>A | 3'Flank (SNP) | VAF 22/265 reads (8%) | called by muse, mutect2
- TAPBPL | c.-63C>T | 5'UTR (SNP) | VAF 92/396 reads (23%) | called by muse, mutect2, varscan2
- TBX22 | c.*1T>G | 3'UTR (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- TEKT4P2 | n.1416T>A | RNA (SNP) | VAF 50/1020 reads (5%) | called by muse, mutect2
- TNNT3 | chr11:1938636 G>T | 3'Flank (SNP) | VAF 22/146 reads (15%) | catalogued as COSV53485219; called by muse, mutect2, varscan2
- UBTFL2 | n.822C>A | RNA (SNP) | VAF 95/820 reads (12%) | catalogued as rs745972728; called by muse, mutect2, varscan2
- VCAN | c.10063+44C>G | Intron (SNP) | VAF 53/356 reads (15%) | called by muse, mutect2, varscan2
- YBX1 | c.166+315C>G | Intron (SNP) | VAF 18/97 reads (19%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+4910G>A | Intron (SNP) | VAF 64/401 reads (16%) | catalogued as rs908589210; called by muse, mutect2, varscan2
- ZNF280D | chr15:56733673 C>G | 5'Flank (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- ZNF497 | c.-111-729A>T | Intron (SNP) | VAF 27/124 reads (22%) | called by muse, mutect2, varscan2
- ZNF812P | n.1452A>C | RNA (SNP) | VAF 12/110 reads (11%) | called by muse, mutect2, varscan2
